Somatic mutation profile of tumor specimen TCGA-CR-7369-01A (aliquot TCGA-CR-7369-01A-11D-2129-08) from TCGA case TCGA-CR-7369, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 60.0 years (21,897 days).
Specimen TCGA-CR-7369-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9546073e-da8a-472e-8c86-3346fd11565d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7369-10A (Blood Derived Normal), aliquot TCGA-CR-7369-10A-01D-2129-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66a58077-54b3-4e4b-85f2-dfccbffafafe

The open-access MAF lists 79 somatic variants for this specimen: 60 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 17, Nonsense Mutation 5, Frame Shift Ins 2, Frame Shift Del 2, Intron 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 25/98 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs121909238, CM051214, COSV100910602, COSV64296545, COSV64296755; ClinVar: pathogenic; called by muse, mutect2
- AHSG | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 138/225 reads (61%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs766181399, COSV56607693; called by muse, mutect2, varscan2
- ANGPT4 | c.133T>G p.Y45D | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101124731; called by muse, mutect2, varscan2
- ASPM | c.3515C>T p.T1172M | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs201067420, COSV54128368; called by muse, mutect2, varscan2
- AVPR1A | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.408); catalogued as COSV100146852; called by muse, mutect2, varscan2
- BABAM2 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 104/464 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1558639513, COSV59622455, COSV59628195; called by muse, mutect2, varscan2
- BEND6 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 60/285 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.979); catalogued as COSV100876848; called by muse, mutect2, varscan2
- BTBD8 | c.794A>G p.Y265C | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745561795, COSV100730274, COSV61544801; called by muse, mutect2, varscan2
- CASZ1 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 92/167 reads (55%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.32); catalogued as COSV100681379; called by muse, mutect2, varscan2
- CCDC40 | c.2832+2T>G p.X944_splice | Splice Site (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100884251; called by muse, varscan2
- CEP120 | c.620C>A p.P207Q | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100071104; called by muse, mutect2, varscan2
- CPA5 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100812321; called by muse, mutect2
- CSRNP3 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as rs369735548, COSV100086138; called by muse, mutect2, varscan2
- DHX30 | c.2218A>G p.I740V (on ENST00000445061 / NM_138615.3; = p.I701V on NM_014966.3) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as rs773733661, COSV53142473; called by muse, mutect2, varscan2
- DIP2A | c.3735C>G p.F1245L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.347); catalogued as COSV100595779; called by muse, mutect2, varscan2
- FAHD2A | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV99272037; called by muse, mutect2, varscan2
- FNDC1 | c.1937A>G p.D646G | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.005); catalogued as COSV99795819; called by muse, mutect2, varscan2
- FNDC7 | c.1120T>C p.C374R | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99601241; called by muse, mutect2, varscan2
- GLIS3 | c.1106T>C p.V369A | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.159); catalogued as COSV100173997; called by muse, mutect2, varscan2
- GLRA3 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.304); catalogued as COSV56869114; called by muse, mutect2, varscan2
- GREM2 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.536); catalogued as rs1044647734, COSV58947633; called by muse, mutect2, varscan2
- HNRNPU | c.1163T>C p.I388T (on ENST00000283179; = p.I450T on NM_004501.3) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.051); catalogued as COSV99310309; called by muse, mutect2, varscan2
- KDM2B | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV65639691; called by muse, mutect2, varscan2
- KIAA1755 | c.3478C>T p.R1160W | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376293680; called by muse, mutect2, varscan2
- LAMB4 | c.1565A>G p.N522S | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV99224065; called by muse, varscan2
- LRBA | c.2909G>T p.G970V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as COSV100841547; called by muse, mutect2, varscan2
- LRFN2 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs778377494, COSV100599563; called by muse, mutect2, varscan2
- MAGIX | c.197-4C>T | Splice Region (SNP) | VAF 82/175 reads (47%) | catalogued as COSV100891885; called by muse, mutect2, varscan2
- NIPBL | c.4352T>G p.L1451* | Nonsense Mutation (SNP) | VAF 28/161 reads (17%) | catalogued as COSV99240633; called by muse, mutect2, varscan2
- NSD2 | c.514A>T p.S172C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100373298; called by muse, mutect2, varscan2
- OR8D2 | c.766A>T p.T256S | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.752); catalogued as COSV100658995; called by muse, mutect2, varscan2
- PCNX1 | c.3733G>A p.E1245K | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV99455629; called by muse, mutect2, varscan2
- PIEZO2 | c.6931C>T p.R2311C | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99554974, COSV99554992; called by muse, mutect2, varscan2
- PLA2G4A | c.1834T>A p.F612I | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); catalogued as COSV100820540; called by muse, mutect2, varscan2
- PLIN2 | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99438920; called by muse, mutect2, varscan2
- PPP1R16B | c.240C>A p.D80E | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100239467, COSV55380394; called by muse, mutect2, varscan2
- PRPS1L1 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV101552934; called by muse, mutect2, varscan2
- PXDNL | c.1648C>A p.Q550K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV100683639; called by muse, mutect2, varscan2
- RAB1A | c.263T>C p.I88T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99560925; called by muse, varscan2
- RAPGEF2 | c.3019T>G p.L1007V | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV100031162; called by muse, varscan2
- RBBP6 | c.41A>G p.Y14C | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100154595; called by muse, mutect2, varscan2
- REG3A | c.247G>C p.A83P | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV59413052; called by muse, mutect2, varscan2
- ROBO1 | c.256A>C p.T86P | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101458717; called by muse, mutect2, varscan2
- SCARB2 | c.1001C>A p.P334H | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53670722; called by muse, mutect2
- SLC5A12 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 65/268 reads (24%) | catalogued as rs760914360, COSV54823292; called by muse, mutect2, varscan2
- ST18 | c.2535G>C p.K845N | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99389636; called by muse, mutect2, varscan2
- TICRR | c.4720C>T p.R1574* | Nonsense Mutation (SNP) | VAF 36/145 reads (25%) | catalogued as rs1302873022, COSV51538579; called by muse, mutect2, varscan2
- TPP2 | c.2135T>C p.L712P | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV101060268; called by muse, mutect2, varscan2
- TTC17 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV99235324; called by muse, mutect2, varscan2
- UBR5 | c.1094A>G p.D365G | Missense Mutation (SNP) | VAF 86/182 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.211); catalogued as COSV99640864; called by muse, mutect2, varscan2
- WDR5B | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1370488638, COSV100413106; called by muse, mutect2, varscan2
- YTHDC2 | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 5/96 reads (5%) | catalogued as COSV99363301; called by muse, mutect2
- ZNF543 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100386772; called by muse, mutect2, varscan2
- ZNF638 | c.3127A>G p.R1043G | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV100038882; called by muse, mutect2, varscan2
- ZPLD1 | c.237C>A p.C79* (on ENST00000466937 / NM_001329788.1; = p.C95* on NM_175056.2) | Nonsense Mutation (SNP) | VAF 76/113 reads (67%) | catalogued as COSV100083233; called by muse, mutect2, varscan2
- CASZ1 | c.1661dup p.M554Ifs*6 | Frame Shift Ins (INS) | VAF 16/31 reads (52%) | called by mutect2, pindel, varscan2
- IGKV2D-30 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); called by muse, mutect2
- PLEC | c.1487dup p.G497Wfs*30 (on ENST00000322810 / NM_201380.4; = p.G387Wfs*30 on NM_000445.5) | Frame Shift Ins (INS) | VAF 29/102 reads (28%) | called by mutect2, pindel, varscan2
- RGS9 | c.1994del p.K665Rfs*27 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- TRIM59 | c.903_904del p.I302Sfs*17 | Frame Shift Del (DEL) | VAF 23/134 reads (17%) | called by mutect2, pindel, varscan2
- ADH6 | c.286C>T p.L96= | Silent (SNP) | VAF 33/126 reads (26%) | catalogued as COSV99422315; called by muse, mutect2, varscan2
- BPIFB4 | c.213C>A p.P71= | Silent (SNP) | VAF 47/177 reads (27%) | catalogued as rs145261889, COSV100971524; called by muse, mutect2
- CUL9 | c.6693C>T p.L2231= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV99335410; called by muse, mutect2, varscan2
- DUSP22 | c.288G>A p.V96= | Silent (SNP) | VAF 58/376 reads (15%) | catalogued as rs756999142, COSV100739773; called by muse, mutect2, varscan2
- IGKV1-27 | c.60C>A p.T20= | Silent (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- LRFN5 | c.1749A>T p.V583= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV99983883; called by muse, mutect2, varscan2
- MROH2B | c.3567G>A p.V1189= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as COSV101270677, COSV68188906; called by muse, mutect2, varscan2
- OR52B2 | c.412C>T p.L138= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV101603944; called by muse, mutect2, varscan2
- PCSK5 | c.3390C>A p.S1130= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV101377391; called by muse, mutect2, varscan2
- PPIL1 | c.216A>G p.R72= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV101033871; called by muse, mutect2, varscan2
- PRDM2 | c.477C>A p.A159= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV99341701; called by muse, mutect2, varscan2
- RNF19B | c.2082C>T p.A694= | Silent (SNP) | VAF 44/170 reads (26%) | catalogued as rs1557562175, COSV99331462; called by muse, mutect2, varscan2
- SFI1 | c.2673G>T p.T891= (on ENST00000400288 / NM_001007467.3; = p.T860= on NM_014775.4) | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100770155; called by muse, mutect2, varscan2
- TH | c.348C>T p.L116= (on ENST00000381178 / NM_199292.3; = p.L85= on NM_000360.4) | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV100147097; called by muse, mutect2, varscan2
- UBE2Q1 | c.891C>T p.S297= | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as rs367889852; called by muse, mutect2, varscan2
- YWHAB | c.165C>T p.G55= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs745735230, COSV62304749; called by muse, mutect2, varscan2
- ZNRF4 | c.420C>T p.N140= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as rs201137254, COSV99706506; called by muse, mutect2, varscan2
- ERCC1 | c.843+22C>A | Intron (SNP) | VAF 48/185 reads (26%) | catalogued as COSV99185292; called by muse, mutect2, varscan2
- PRR12 | c.52-411A>T | Intron (SNP) | VAF 14/37 reads (38%) | catalogued as COSV101330675; called by muse, mutect2, varscan2
